PECGS case C083-000063 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/93343e9c-610a-4211-b1ed-ff74ce18bf98

Demographics
Sex at birth: female; Age at index: 44 years; Year of birth: 1976; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 43.6 years (15,925 days); AJCC pathologic stage: Stage IIIB; Progression or recurrence: no.

Other clinical attributes
- BMI: 26.36; Menopause status: Premenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: No.

Biospecimens (2 samples)
- Sample C083-000063_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000063_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
